Somatic mutation profile of tumor specimen ALCH-B1RH-TTP1-A (aliquot ALCH-B1RH-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1RH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.1 years (29,981 days).
Specimen ALCH-B1RH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e97540bf-aa30-4626-aac9-c6bfc80d16ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RH-NB1-A (Blood Derived Normal), aliquot ALCH-B1RH-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd621a73-a434-4d0d-ba7b-872ca0920b24

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, RNA 3, Intron 3, Splice Site 2, Frame Shift Del 2, Splice Region 1, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 28/197 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- BCL11B | c.784C>T p.R262W (on ENST00000357195 / NM_001282237.2; = p.R191W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763799880; called by muse, mutect2, varscan2
- BRD9 | c.996del p.S333Afs*24 | Frame Shift Del (DEL) | VAF 32/306 reads (10%) | catalogued as COSV100057532; called by mutect2, varscan2
- CACNG7 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1310679798, COSV55814371, COSV55817430; called by muse, mutect2
- CST9 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as rs896900132, COSV65402432; called by muse, mutect2
- CYP4F3 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV99657866; called by muse, mutect2, varscan2
- JMJD4 | c.566+1G>C p.X189_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as rs751904654; called by mutect2, varscan2
- LMAN2 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.771); catalogued as rs11541334; called by muse, mutect2, varscan2
- MTMR3 | c.2786A>G p.N929S | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.97); catalogued as rs149113635; called by muse, mutect2, varscan2
- OBI1 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs754724403, COSV56144814; called by muse, mutect2, varscan2
- PCDHGA8 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV53963990; called by muse, mutect2, varscan2
- PCDHGB1 | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53913423; called by muse, mutect2, varscan2
- PTPRZ1 | c.4192G>C p.A1398P | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV66444340; called by muse, mutect2, varscan2
- SHANK2 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs911201371, COSV53624402; called by muse, mutect2
- SIX3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53227235; called by muse, mutect2, varscan2
- TECRL | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV67091258, COSV99059912; called by muse, mutect2
- TECRL | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV67091663; called by muse, mutect2
- TEK | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.08); catalogued as rs573385848; called by muse, mutect2, varscan2
- TMEM132C | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs780140810, COSV59413274; called by muse, mutect2
- ZMYM6 | c.1196G>T p.S399I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as rs1464567285; called by muse, mutect2
- ZNF469 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558293585; called by muse, mutect2, varscan2
- ACP4 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ASPG | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- DENND10 | c.254_255dup p.T86* | Frame Shift Ins (INS) | VAF 10/88 reads (11%) | called by pindel, varscan2
- ERCC4 | c.1662C>G p.I554M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GK | c.1549A>G p.M517V (on ENST00000427190 / NM_001205019.2; = p.M511V on NM_000167.6) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, varscan2
- IGKV2D-26 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LONP1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.216); called by muse, mutect2
- MED12 | c.5353A>T p.K1785* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | called by muse, mutect2, varscan2
- NAV2 | c.6155A>T p.D2052V (on ENST00000396087 / NM_001244963.2; = p.D1993V on NM_145117.5) | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT3 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PEG10 | c.-224+6T>C | Splice Region (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- PEX5L | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLAAT3 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR2F | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PSMA7 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RANBP9 | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM10 | c.2199_2205del p.S733Rfs*67 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- RFX8 | c.1268C>A p.T423N (on ENST00000646446; = p.T352N on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RIF1 | c.1355A>G p.K452R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.287); called by muse, mutect2
- SORCS1 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- TBC1D2 | c.2277C>G p.D759E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TSNAXIP1 | c.-115-1G>T | Splice Site (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- TSPAN31 | c.163T>G p.F55V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF37A | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.10631A>G p.D3544G (on ENST00000437464; = p.D3572G on NM_001367624.2) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF808 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- BNIP3 | c.603C>T p.H201= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- CCDC57 | c.1908C>G p.A636= | Silent (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- FARP1 | c.459C>T p.D153= | Silent (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- KCNK12 | c.6C>G p.S2= | Silent (SNP) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- MBOAT7 | c.165C>T p.V55= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- MPP2 | c.1269C>T p.Y423= (on ENST00000461854 / NM_001278372.2; = p.Y399= on NM_005374.5) | Silent (SNP) | VAF 32/245 reads (13%) | catalogued as rs1485159119; called by muse, mutect2, varscan2
- MTUS2 | c.1977C>T p.D659= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs778158356, COSV70924679; called by muse, mutect2, varscan2
- NANOS1 | c.840C>T p.R280= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1360774441; called by muse, mutect2
- POLR2F | c.303G>A p.K101= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as rs1162068337; called by muse, mutect2, varscan2
- SLIT1 | c.1761C>G p.G587= | Silent (SNP) | VAF 44/321 reads (14%) | called by muse, mutect2, varscan2
- C6orf223 | n.53A>G | RNA (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- CEP131 | c.3178-35C>T | Intron (SNP) | VAF 45/251 reads (18%) | called by muse, mutect2, varscan2
- FAM197Y1 | n.374G>A | RNA (SNP) | VAF 7/502 reads (1%) | catalogued as rs776135058; called by muse, mutect2
- MINPP1 | c.*25T>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- PCM1 | c.1472+10_1472+14dup | Intron (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel
- SIPA1L3 | c.2030-34G>C | Intron (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- TMEM183B | n.524G>A | RNA (SNP) | VAF 48/354 reads (14%) | catalogued as rs184565083; called by muse, varscan2
